Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4747, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4747-01A (Primary Tumor).

[page 1 of 3]
TCGA-CM-4747

* Addendum *

Clinical Diagnosis & History:

ulcerated invasive ileocecal valve, also with 3 liver nodules in segments 7, 4B, and 5 measuring 2.2 x 1.7, 1 x 1.6 cm, 1.7 cm x 1.3 cm.

Specimens Submitted:

- 1: SP: Right hemicolectomy
- 2: SP: Small bowel mesenteric lymph node

DIAGNOSIS:

1. LARGE BOWEL, RIGHT HEMICOLECTOMY;
- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: CECUM.
- TUMOR SIZE: LENGTH IS 5.5 CM, WIDTH IS 3.5 CM, MAXIMAL THICKNESS IS 3.5 CM.
- GROSS CONFIGURATION: FUNGATING.
- PREEEXISTING POLYP (AT THE SITE OF THE CARCINOMA): IDENTIFIED, OF TUBULOVILLOUS ADENOMA TYPE.
- TUMOR INVASION: INVASION THROUGH BOWEL WALL WITH INVOLVEMENT OF SEROSA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: IDENTIFIED.
- VASCULAR INVASION: SUSPICIOUS FOR VASCULAR INVASION.
- PERINEURAL INVASION: IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: DIVERTICULA DISEASE.
- THE PATHOLOGIC STAGE IS (): PT4.
- LYMPH NODES: NUMBER WITH METASTASES: 2, NUMBER EXAMINED: 29.
- THE PATHOLOGIC STAGE IS (): pN1.
2. LYMPH NODE, SMALL BOWEL MESENTERY; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

[page 2 of 3]
1) The specimen is received fresh, labeled "Right hemicolectomy" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 24 cm in length and 5 cm in circumference at the proximal resected margin. The remaining colon measures 29 cm in length with a circumference of 6 cm at the distal resected margin. The attached appendix measures 5 cm in length and averages 0.6 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 4 cm in thickness. The serosa is inked black. The specimen contains a fungating mass (5.5 cm in length and 3.5 cm in width) occupying the cecum, surrounding the ileocecal valve with sparing of the appendical orifice. Sectioning shows that the tumor invades into the subserosa. The depth of invasion is 3.5 cm grossly. The remaining colonic mucosa shows rare diverticula. The distal ileal mucosa shows occasional diverticula and small mucosal polyps. The specimen is submitted for lymph node dissection. Representative sections of the specimen are submitted for permanent sections.

Summary of sections:

P -- proximal margin shave

D -- distal margin shave

Mmass

D -- deepest extent of mass

A -- appendix representative sections

I -- ileal mucosa with polyps

C -- representative sections, colon

LN -- lymph nodes

2) The specimen is received in formalin, labeled "Small bowel mesenteric lymph node" and consists of a 2.3 x 1.6 x 0.4 cm, firm, fatty, tan-red lymph node, which is bisected to reveal smooth, focally hemorrhagic, tan-pink cut surfaces. The lymph node is entirely submitted.

Summary of sections:

BLN -- bisected lymph nodes

Summary of Sections:

Part 1: SP; Right hemicolectomy

Block	Sect.	Site	PCs
1	A		1

** Continued on next page **

[page 3 of 3]
1	C	1
2	D	2
1	DM	1
2	I	2
6	LN	24
4	M	4
1	PM	1

Part 2: SP: Small bowel mesenteric lymph node

Block	Sect.	Site	PCs
2		BLN	2

#1) SITE: LARGE BOWEL
- IMMUNOHISTOCHEMICAL STAINING FOR DNA MISMATCH REPAIR PROTEINS HAS BEEN PERFORMED. THE RESULTS ARE AS FOLLOWS:
MLH1: STAINING PRESENT IN TUMOR
MSH2: STAINING PRESENT IN TUMOR
MSH6: STAINING PRESENT IN TUMOR
PMS2: STAINING PRESENT IN TUMOR
CONCLUSION: IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR PROTEINS IS RETAINED IN THE TUMOR.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** End of Report **

Source: NCI Genomic Data Commons file 7198b086-6d0a-4360-9f2f-772e11318e05 (TCGA-CM-4747.DA76CC38-102A-4F1C-AB04-430B9EEF7899.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).